Gene-level copy-number profile of tumor specimen TARGET-40-0A4I6O-01A from TARGET case TARGET-40-0A4I6O, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.4 years (6,738 days).
Specimen TARGET-40-0A4I6O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.f89e64ce-62dc-5283-9bb9-68d728c4aed4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I6O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/82438280-447b-4a33-ba7b-b832e4cff020

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 507; copy number 1: 5,842; copy number 2: 26,052; copy number 3: 20,014; copy number 4: 5,226; copy number 5: 1,564; copy number 6: 914; copy number 7: 31; copy number 8: 82; copy number 9: 29.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:244,969,705–245,134,090, 5 genes (within-gene range 0–2): EFCAB2, RNU6-1089P, RNU6-999P, AL589763.1, RNU1-132P.
- chr1:245,206,444–245,283,089, 2 genes: KIF26B-AS1, DNAJC19P8.
- chr3:116,582,552–117,027,039, 9 genes: RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr11:948,421–948,524, 1 gene: RNU6-1025P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,620 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–151,047,720, 281 genes, copy number 6 (broad region; genes not listed).
- chr1:151,700,058–163,509,595, 560 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:165,476,838–168,075,843, 67 genes, copy number 6 (broad region; genes not listed).
- chr1:168,375,524–169,500,182, 27 genes, copy number 6: MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1, CCDC181, SLC19A2, AL021068.1, Z99572.1.
- chr1:171,683,128–172,468,831, 19 genes, copy number 5: RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105.
- chr2:88,811,186–88,861,563, 1 gene, copy number 9 (within-gene range 3–9): AC244205.1.
- chr2:88,857,161–89,160,366, 28 genes, copy number 9: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21.
- chr7:2,474,844–6,835,794, 99 genes, copy number 5 (broad region; genes not listed).
- chr7:54,621,025–69,174,450, 363 genes, copy number 5–6 (broad region; genes not listed).
- chr7:69,187,833–69,189,318, 1 gene, copy number 5: AC069280.1.
- chr9:98,847,172–98,891,937, 2 genes, copy number 5: AL136084.1, NME2P3.
- chr14:18,333,726–30,373,115, 526 genes, copy number 5–8 (broad region; genes not listed).
- chr14:105,736,343–106,443,583, 117 genes, copy number 6 (broad region; genes not listed).
- chr17:46,029,916–46,225,389, 1 gene, copy number 7 (within-gene range 3–7): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 7: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.
- chr19:19,033,575–36,331,770, 523 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,391. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
